Somatic mutation profile of tumor specimen TARGET-20-PANVGP-04A (aliquot TARGET-20-PANVGP-04A-02D) from TARGET case TARGET-20-PANVGP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.6 years (4,950 days).
Specimen TARGET-20-PANVGP-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cebe0259-c194-4039-90b0-f2b97f42e699.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANVGP-14A (Bone Marrow Normal), aliquot TARGET-20-PANVGP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9e8cdd0-547a-4eed-94c2-c3bb3c77ddb8

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRF | c.448_449insTT p.R150Lfs*27 | Frame Shift Ins (INS) | VAF 38/93 reads (41%) | catalogued as COSV63445852; called by mutect2, pindel*, varscan2
- ETV6 | c.305_309delinsCCTGGGCCT p.F102Sfs*11 | Frame Shift Ins (INS) | VAF 48/109 reads (44%) | called by pindel, varscan2*
- COL1A1 | c.3532-33C>T | Intron (SNP) | VAF 29/87 reads (33%) | catalogued as rs775809193; called by muse, mutect2, varscan2
